MMRF case MMRF_1982 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/22773cc4-bc3b-48f6-8529-2f14b7dff462

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 52 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 52.3 years (19,112 days); ISS stage: I; Days to last known disease status: 900 days (2.5 years); Days to last follow up: 900 days (2.5 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 91 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 91 days; Days to treatment end: 165 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 172 days; Days to treatment end: 172 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -65 (ECOG 2): M Protein 3.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 62.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.74 mg/dL; Immunoglobulin G 45.3 g/L; Immunoglobulin A 0.25 g/L; Immunoglobulin M 0.19 g/L; Beta 2 Microglobulin 3.1 µg/mL; Lactate Dehydrogenase 3.57 µkat/L; Hemoglobin 4.59 mmol/L; Leukocytes 5.5 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 312 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.25 mmol/L; Albumin 37 g/L; Total Protein 10.1 g/dL; Glucose 6.05 mmol/L.
- Day 15: Hemoglobin 6.51 mmol/L; Leukocytes 9 ×10⁹/L; Platelets 273 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.05 mmol/L; Albumin 35 g/L; Total Protein 6.7 g/dL; Glucose 7.15 mmol/L.
- Day 121: M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.57 mg/dL; Immunoglobulin G 4.58 g/L; Immunoglobulin A 0.16 g/L; Immunoglobulin M 0.34 g/L; Lactate Dehydrogenase 4.05 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 5.7 ×10⁹/L; Platelets 212 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.2 mmol/L; Albumin 37 g/L; Total Protein 6.3 g/dL; Glucose 3.96 mmol/L.
- Day 206: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.39 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.67 mg/dL; Immunoglobulin G 5.42 g/L; Immunoglobulin A 0.29 g/L; Immunoglobulin M 0.45 g/L; Hemoglobin 6.57 mmol/L; Leukocytes 2.6 ×10⁹/L; Absolute Neutrophil 1.2 ×10⁹/L; Platelets 309 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 2.14 mmol/L; Calcium 2.25 mmol/L; Albumin 36 g/L; Total Protein 6.3 g/dL; Glucose 5.06 mmol/L.
- Day 239: Lactate Dehydrogenase 4.3 µkat/L; Hemoglobin 6.88 mmol/L; Leukocytes 3 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 205 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.43 mmol/L; Albumin 42 g/L; Total Protein 6.8 g/dL; Glucose 5.78 mmol/L.
- Day 324: Serum Free Immunoglobulin Light Chain, Kappa 0.515 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.232 mg/dL; Hemoglobin 7.44 mmol/L; Leukocytes 2.6 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 205 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.3 mmol/L; Albumin 40 g/L; Total Protein 6.8 g/dL; Glucose 4.79 mmol/L.
- Day 445: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.62 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.77 mg/dL; Immunoglobulin G 7.91 g/L; Immunoglobulin A 0.4 g/L; Immunoglobulin M 0.25 g/L; Hemoglobin 7.32 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 212 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.33 mmol/L; Albumin 40 g/L; Total Protein 7 g/dL; Glucose 4.73 mmol/L.
- Day 543: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.49 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.62 mg/dL; Immunoglobulin G 9.24 g/L; Immunoglobulin A 0.47 g/L; Immunoglobulin M 0.25 g/L; Hemoglobin 7.69 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 201 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.43 mmol/L; Albumin 42 g/L; Total Protein 7.5 g/dL; Glucose 5.23 mmol/L.
- Day 641: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.68 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.38 mg/dL; Immunoglobulin G 10.6 g/L; Lactate Dehydrogenase 3.45 µkat/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Albumin 40 g/L; Total Protein 7.2 g/dL; Glucose 5.78 mmol/L.
- Day 732: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.87 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.17 mg/dL; Lactate Dehydrogenase 3.62 µkat/L; Hemoglobin 7.56 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 199 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 2.86 mmol/L; Calcium 2.3 mmol/L; Albumin 39 g/L; Total Protein 7.5 g/dL; Glucose 5.28 mmol/L.
- Day 816: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.26 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.01 mg/dL; Immunoglobulin G 11.1 g/L; Lactate Dehydrogenase 3.63 µkat/L; Hemoglobin 8.06 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 171 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.28 mmol/L; Albumin 40 g/L; Total Protein 7.3 g/dL; Glucose 5.06 mmol/L.
- Day 900: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.99 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.88 mg/dL; Immunoglobulin G 12.2 g/L; Hemoglobin 7.75 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 225 ×10⁹/L.

Other clinical attributes
- Day -65: Weight: 74 kg; Height: 160 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1982_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -65 days.
- Sample MMRF_1982_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -65 days.
